National Lung Screening Trial (NLST) participant 100619 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 68 years; Gender: male; Race: American Indian or Alaskan Native; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 32): Negative screen, significant abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 130 mA, display field of view 36 cm, reconstruction filter GE, other.
- T1 (day 378): Negative screen, significant abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 75 mA, 43 effective mAs, display field of view 35 cm, reconstruction filter GE Standard / GE Bone.
- T2 (day 704): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 75 mA, 43 effective mAs, display field of view 35 cm, reconstruction filter GE Standard / GE Bone.

Abnormalities recorded by the reading radiologist on the CT screens (7 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Significant cardiovascular abnormality.
- T0 abnormality 2: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 1: Significant cardiovascular abnormality; pre-existing on earlier images (earliest visible day 32); interval change does not warrant further investigation.
- T1 abnormality 2: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 3: Emphysema.
- T2 abnormality 1: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T2 abnormality 2: Other minor abnormality noted.

Lung cancer (2 primary lung cancer records; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T4; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,764, study year T4. Site: lower lobe of lung (ICD-O-3 C34.3), determined from histology. Primary tumour location: right lower lobe. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Grade: well differentiated (G1). Tumour size on pathology: 15 mm. AJCC 6th edition staging: stage IIIA (best stage, from pathologic TNM); clinical T1 N1 M0 (stage IIA); pathologic T1 N2 M0 (stage IIIA). AJCC 7th edition staging: stage IIIA; clinical T1a N2 M0; pathologic T1a N2 M0.
2. Subsequent primary lung cancer, diagnosed day 1,764, study year T4. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Grade: poorly differentiated (G3). Tumour size on pathology: 25 mm. AJCC 6th edition staging: stage IIIA (best stage, from pathologic TNM); clinical T2 N1 M0 (stage IIB); pathologic T1 N2 M0 (stage IIIA). AJCC 7th edition staging: stage IIIA; clinical N1 M0; pathologic T1b N2 M0.

Follow-up
Last known free of lung cancer: day 1,434.
